Surgical pathology report (de-identified scan), TCGA case TCGA-HZ-A49H, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-HZ-A49H-01A (Primary Tumor).

[page 1 of 5]
Patient Results

F

Surgical Pathology

Final

Path Report

Final

SURGICAL PATHOLOGY REPORT

ACCESSION NO. :

Final Diagnosis(es):

- (A) Bile duct margin, biopsy: Negative for malignancy.
- (B) Pancreas margin, biopsy: Negative for malignancy.
- (C) Stomach, gallbladder, head of pancreas, bile duct, duodenum, small bowel, Whipple's procedure:
- 1) Pancreatic adenocarcinoma, moderately differentiated.
- 2) Tumor measures 2.8 cm in greatest dimension.
- 3) Tumor extends through the duodenal wall.
- 4) pT3 N1
- 5) 1 of 44 lymph nodes positive for metastatic carcinoma (2 mm in maximum dimension).
- 6) Perineural and lymphovascular invasion identified.
- 7) See Synoptic report, below.
- (D) Lymph node, superior pancreatic, excision: Negative for metastatic carcinoma.
- (E) Lymph node, hepatic duodenal, excision: Negative for metastatic carcinoma.
- (F) Lymph node, celiac, excision: Negative for metastatic.

Synoptic Report:

Specimens: Head of pancreas, duodenum, stomach, common bile duct and gallbladder.

Procedure: Pancreaticoduodenectomy (Whipple resection), partial pancreatectomy.

Tumor Site: Pancreatic head.

Tumor Size: 2.8 cm in greatest dimension.

Histologic Type: Ductal adenocarcinoma.

Histologic Grade: G2: Moderately differentiated.

Microscopic Tumor Extension: Tumor invades duodenal wall.

Margins: Margins uninvolved by invasive carcinoma.

Distance of invasive carcinoma from closest margin: 3 mm from posterior pancreatic soft tissue.

Treatment Effect: Not known.

Lymphovascular Invasion: Present.

Perineural Invasion: Present.

Pathologic Staging:

Primary Tumor: pT3: Tumor extends beyond the pancreas but without involvement of the celiac axis or the superior mesenteric artery.

Regional Lymph Nodes: pN1: Regional lymph node metastasis.

Number of Lymph Nodes Examined: 47

Number of Lymph Nodes Involved: 1 (2 mm in maximum dimension).

Additional Pathologic Findings: Chronic pancreatitis.

100-0-3
adenocarcinoma, duct, nos 8500/3
Site = pancreas, head C25.0

ju
9/21/12

Printed from: Default

Page: 1 of 5

[page 2 of 5]
Patient Results

F

Electronically Signed

MD (Fellow)

Specimen(s) Received:

A: Bile duct margin

B: Pancreas margin

C: Stomach, gallbladder, head of pancreas, bile duct, duodenum, small bowel

D: Superior pancreatic LN

E: Hepatic duodenal LN

F: Celiac LN

Clinical History:

Pancreatic cancer.

(A) Stitch marks margin of interest.

(B) Stitch marks margin of interest.

(C) Tumor Bank.

Intraoperative Consultation:

Time Received:

Time Reported:

FSA1: Bile duct margin: Negative for malignancy (1 block).

FSB1: Pancreas margin: Negative for malignancy (1 block).

, M.D.

(Resident)

Gross Description:

(A) (bile duct margin) Received fresh for frozen section evaluation with a stitch that marks the margin of interest is an annular segment of gray-pink rubbery tissue that is 1.6 cm in diameter x 0.4 cm long and 0.3 cm thick, having scant tan inspissated material within the lumen. The specimen is entirely submitted fresh for frozen section evaluation in cassette FSA1.

(B) (pancreas margin - the stitch marks the margin of interest) Received fresh for frozen section evaluation is a 2.6 x 1.1 x 0.4 cm thick portion of tan-pink lobulated pancreatic parenchyma with an eccentrically located patent lumen 0.3 cm in diameter consistent with a ductule. The specimen is entirely submitted en face, fresh for frozen section evaluation in cassette FSB1.

(C) (stomach, gallbladder, head of pancreas, bile duct, duodenum, small bowel)

Specimen components and dimensions: Received fresh for Tumor Bank sampling is a head of pancreas that measures anterior to posterior 5.5 cm, superior to inferior 3.8 cm and medial to lateral 3.4 cm. The portion of distal stomach measures 10.5 cm along the greater curvature, 5.8 cm along the lesser curvature, 5.8 cm along the lesser curvature and 2.0 cm from anterior to posterior. The portion of proximal duodenum measures 21.0 cm in length and 2.8 cm in diameter. The gallbladder is attached and measures 8.5 x 4.6 x 4.0 cm. The common bile duct is stented. The margins are inked as follows:

Printed from: Default

Page: 2 of 5

[page 3 of 5]
Patient Results

F

Pancreatic head anterior margin yellow, main pancreatic duct red, uncinata margin green, vascular notch margin indigo, common bile duct margin blue, posterior pancreatic margin black, and the mucosa of the common bile duct orange.

Size, appearance, and location of tumor: The tumor is located within the head of the pancreas. Its site of origin appears to be adjacent to the ampulla of Vater within the parenchyma of the pancreas itself and measures 1.9 cm anterior to posterior, 2.8 cm superior to inferior. The tumor appears to efface the normal morphology of the normal yellow lobulated pancreas and is replaced by a vague dull gray pale tan appearance with ill-defined and vague borders.

Gross impression of invasive growth: The tumor does not appear to grossly involve the bile duct or the pancreatic ducts and appears limited to within the pancreatic parenchyma showing no gross involvement with the duodenal mucosa and appears to abut the ampulla.

Closest resection margins and distance: The ampulla, within 0.3 cm, the anterior margin within 0.3 cm.

Other findings: the tumor is free of the uncinata, vascular and main pancreatic duct margin and shows no gross involvement with the common bile duct margin.

Uninvolved tissues: Soft to rubbery, yellow lobulated pancreas with normal caliber ducts throughout the pancreas. The gallbladder is red-brown, heavily congested with a smooth serosa, 0.3 to 0.6 cm thick walls and bile-stained green, velvety mucosal surfaces filled with green mucoid and viscous bile showing no calculi. The cystic duct 0.2 cm in diameter and showing no gross evidence of tumor. The stomach shows heavily denuded mucosal surfaces corresponding with gastritis and the duodenum is of normal tan-brown tightly folded mucosa showing no focal lesion.

Lymph nodes attached: There are three within the pericomaon bile duct region, five within the posterior peripancreatic soft tissue, nine within the anterior peripancreatic soft tissue and four within the gastro-omental soft tissue of the greater curvature with the lymph nodes ranging from 0.3 to 2.2 cm in greatest dimension, the largest near the pericomaon bile duct region.

Blocks submitted:

C1 - tumor to ampulla, common bile duct duodenum and pancreatic parenchyma

C2-C3 - tumor to distal common bile duct divided

C4 - additional sections of tumor to ampulla

C5 - central section of tumor

C6 - representative section of tumor to anterior and posterior margins

C7 - main pancreatic duct margin

C8 - common bile duct margin

C9-C10 - vascular notch margin serially sectioned sequentially

[page 4 of 5]
Patient Results

F

from posterior to anterior

C11-C12 - uncinata margin sequentially from posterior to anterior

C13-C15 - posterior/retroperitoneal margin submitted sequentially from superior to inferior

C16-C17 - proximal gastric margin

C18 - representative sections of stomach

C19 - representative sections of gallbladder

C20 - representative sections of duodenum

C21 - representative sections of distal duodenal margin

C22 - two pericommmon bile duct lymph nodes intact

C23 - six lymph nodes intact from the anterior peripancreatic region

C24 - three lymph nodes intact from the anterior peripancreatic region

C25 - four lymph nodes from the gastro-omental region (the four lymph nodes from the posterior peripancreatic region are submitted as part of the posterior margin en face sections)

(D) (superior pancreatic lymph node) Received in formalin is a tan-pink rubbery lymph node that is 1.2 cm in greatest dimension. It is trisected and submitted entirely in cassette D1.

(E) (hepatic duodenal lymph node) Received in formalin is a 3.2 x 2.9 x 1.0 cm tan to red-brown rubbery tissue. It is serially sectioned and submitted entirely in cassettes E1 and E2.

(F) (celiac lymph node) Received in formalin is a tan-pink to yellow, soft to rubbery tissue fragment that has a smooth glistening external surface and measures 2.7 x 1.5 x 0.4 cm. It is serially sectioned and submitted entirely in cassette F1.

Microscopic Description:

Complete microscopic evaluation has been performed.

Appropriately reacting controls have been performed and evaluated for all stains on this case as required.

Histopathology has a list of IH antibodies that are regulated as analyte specific reagents (ASR's). These assays were developed and their performance characteristics determined by the Histopathology Laboratory in the Department of Pathology at The

They

have not been cleared by the US Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary for the ASR's. These tests are not investigational and are used in standard clinical care. In cases where Immunohistochemistry testing is performed, the following antibodies and their respective clones may be used to determine therapy for the patient: EFGR(31G7), ER(SP1), PR(1E2), Her2neu(4B5), CD117(Poly), CD20(L26).

Unless otherwise stated in the report, all tissue tested for

[page 5 of 5]
Patient Results

F

ERPR by IHC, Her2 by IHC and/or HER2 by FISH have been fixed as per ANP.22998 for a minimum of 6 hours and a maximum of 48 hours.

ER, PR, Ki-67, p53 are reported as a semi-quantitative percentage of positively stained nuclei. Her-2/neu and EGFR are scored as follows: No staining at all is scored as (0), weak, incomplete membrane staining in any proportion of cells is scored as (1+), less than strong but complete staining in any proportion of cells or complete strong staining in less than 30% of cells is scored as (2+), and strong complete staining in more than 30% of cells is scored as (3+). All studies are performed on tissue fixed in 10% neutral buffered formalin and embedded in paraffin unless otherwise stated in the report.

lw
8/30/12

Printed from: Default

End of Report

Page: 5 of 5

Source: NCI Genomic Data Commons file 599d4276-958b-4ca0-b091-dff0c491b3b7 (TCGA-HZ-A49H.6F534DEF-868A-4F2C-8A57-E4F738B285DF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).